Gene-level copy-number profile of tumor specimen TCGA-CV-5434-01A from TCGA case TCGA-CV-5434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.7 years (22,182 days).
Specimen TCGA-CV-5434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d7d0f0f1-2bfb-4713-9513-862cf5d91a7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97cc9f16-a63e-413c-93a2-7d490e3a94da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 160; copy number 1: 1,785; copy number 2: 20,618; copy number 3: 17,867; copy number 4: 9,802; copy number 5: 5,559; copy number 6: 2,163; copy number 7: 1,476; copy number 8: 107; copy number 9: 80; copy number 10: 15; copy number 11: 62; copy number 12: 119; copy number 17: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5434-01A-01D-1682-01): tumor purity 0.58, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 160 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–4,708,399, 63 genes (within-gene range 0–10) (broad region; genes not listed).
- chr9:6,195,934–6,331,900, 5 genes: GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3.
- chr9:7,796,500–7,961,224, 3 genes (within-gene range 0–4): DMAC1, AL135923.2, AL135923.1.
- chr9:8,700,595–8,864,772, 4 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1.
- chr9:15,553,043–16,061,663, 1 gene (within-gene range 0–11): CCDC171.
- chr9:15,776,181–18,910,950, 18 genes (within-gene range 0–10): RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1.
- chr9:19,507,452–22,029,594, 65 genes (within-gene range 0–9) (broad region; genes not listed).
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,582 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:142,131,178–211,299,189, 1,017 genes, copy number 5–7 (broad region; genes not listed).
- chr3:139,837,220–198,222,513, 1,011 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–19,234,487, 353 genes, copy number 5 (broad region; genes not listed).
- chr7:63,011,463–122,062,036, 1,105 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr7:129,144,707–159,233,377, 696 genes, copy number 5 (broad region; genes not listed).
- chr8:113,950,886–145,066,685, 511 genes, copy number 6–7 (broad region; genes not listed).
- chr9:4,709,556–6,066,714, 45 genes, copy number 5–10: AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1.
- chr9:8,314,246–10,612,723, 1 gene, copy number 5 (within-gene range 0–17): PTPRD.
- chr9:8,936,079–15,544,294, 65 genes, copy number 5–17 (broad region; genes not listed).
- chr9:15,588,355–15,588,615, 1 gene, copy number 11: HMGN2P16.
- chr9:18,573,306–19,051,025, 6 genes, copy number 10: MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA.
- chr9:19,371,386–19,464,524, 8 genes, copy number 9: AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1.
- chr9:21,994,139–22,128,103, 1 gene, copy number 5 (within-gene range 0–5): CDKN2B-AS1.
- chr9:22,002,903–25,089,151, 25 genes, copy number 5–7: CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:137,776,539–137,838,516, 2 genes, copy number 9: AL590627.1, MIR602.
- chr14:21,768,489–29,500,460, 310 genes, copy number 5–9 (broad region; genes not listed).
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 4–5): NRXN3.
- chr14:78,695,321–85,239,474, 55 genes, copy number 5: AC009396.2, AC009396.3, AC009396.1, AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1, AF123462.1, DIO2, DIO2-AS1, CEP128, HMGN2P2, TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1, AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1.
- chr17:22,606,388–28,022,464, 46 genes, copy number 5: AC131055.1, AC131274.3, AC131274.1, AC131274.2, AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70.
- chr17:28,061,967–28,062,068, 1 gene, copy number 5: Vault.
- chr17:29,560,547–35,130,732, 215 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:20,946,906–34,224,952, 210 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:27,638,483–41,096,195, 517 genes, copy number 5–12 (broad region; genes not listed).
- chr20:87,250–24,226,013, 484 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:30,484,925–39,815,097, 292 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
